Somatic mutation profile of tumor specimen TCGA-B0-5709-01A (aliquot TCGA-B0-5709-01A-11D-1534-10) from TCGA case TCGA-B0-5709, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.5 years (22,843 days).
Specimen TCGA-B0-5709-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c46d407f-ba96-40c0-adce-4dce733128bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5709-11A (Solid Tissue Normal), aliquot TCGA-B0-5709-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/412e1877-ba96-44b2-8fd7-27b920a30aaf

The open-access MAF lists 75 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 17, Frame Shift Del 7, Nonsense Mutation 4, Frame Shift Ins 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs199633532, CM067634, COSV54368245; ClinVar: uncertain significance; called by mutect2, varscan2
- ACE2 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 52/320 reads (16%) | catalogued as COSV53024701, COSV99382639; called by muse, mutect2, varscan2
- ADGRV1 | c.18013C>A p.H6005N | Missense Mutation (SNP) | VAF 232/1455 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV67983588; called by muse, varscan2
- ARHGEF11 | c.3915G>T p.R1305S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); catalogued as COSV59353858; called by muse, mutect2, varscan2
- ARID1A | c.4940A>G p.E1647G | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100251702; called by muse, varscan2
- BAP1 | c.1081del p.L361* | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as COSV56240318; called by mutect2, pindel, varscan2
- C3orf33 | c.221G>T p.R74I (on ENST00000340171 / NM_001308229.2; = p.R31I on NM_173657.2) | Missense Mutation (SNP) | VAF 78/517 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV60896804; called by muse, mutect2, varscan2
- CD27 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV56949969; called by muse, mutect2, varscan2
- CNOT6L | c.571G>T p.V191F (on ENST00000504123 / NM_001286790.2; = p.V186F on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/351 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53697599, COSV53698870; called by muse, mutect2
- COL4A5 | c.4948G>A p.A1650T | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60360191; called by muse, mutect2, varscan2
- CSAG1 | c.56del p.G19Efs*16 | Frame Shift Del (DEL) | VAF 79/462 reads (17%) | catalogued as COSV63400467; called by mutect2, pindel, varscan2
- DDX3X | c.535G>C p.E179Q (on ENST00000399959; = p.E180Q on NM_001356.5) | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV67863417; called by muse, mutect2, varscan2
- DHX35 | c.1511G>T p.C504F | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52669586; called by muse, mutect2, varscan2
- DNAH9 | c.6184C>T p.P2062S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV52345784; called by muse, mutect2, varscan2
- FEM1B | c.1139A>T p.N380I | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV60988343; called by muse, mutect2, varscan2
- GCFC2 | c.1705C>A p.L569I | Missense Mutation (SNP) | VAF 90/595 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV58080685, COSV58083347; called by muse, mutect2, varscan2
- HOOK1 | c.1447G>C p.G483R | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV64618562; called by muse, varscan2
- HOXB13 | c.548G>T p.C183F | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV51705821; called by muse, mutect2, varscan2
- IGF2R | c.6318G>T p.K2106N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV63628388; called by muse, mutect2, varscan2
- JPH1 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV60610252; called by muse, mutect2
- KLF10 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV53435290; called by muse, mutect2, varscan2
- KRT5 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.251); catalogued as rs200072843, COSV52860212; called by muse, mutect2
- MS4A14 | c.659A>C p.Q220P | Missense Mutation (SNP) | VAF 44/423 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV55734348; called by muse, mutect2, varscan2
- MYCBP2 | c.13465T>C p.F4489L (on ENST00000357337; = p.F4527L on NM_015057.5) | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV62016102; called by muse, varscan2
- MYOM1 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV55290163; called by muse, mutect2, varscan2
- NAV1 | c.4772T>C p.F1591S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99818845; called by muse, varscan2
- OGG1 | c.1243C>G p.H415D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV99844743; called by muse, mutect2, varscan2
- POU2F1 | c.1023G>T p.K341N (on ENST00000541643 / NM_001365848.1; = p.K364N on NM_002697.4) | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54815767; called by muse, mutect2, varscan2
- PSMB7 | c.32T>A p.V11D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52330215; called by muse, mutect2, varscan2
- RCC1L | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs782638012, COSV57320160; called by muse, mutect2
- REXO5 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54471708; called by muse, mutect2, varscan2
- RIN2 | c.2420G>A p.R807Q (on ENST00000255006 / NM_001242581.1; = p.R758Q on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs755864961, COSV54787120; called by muse, mutect2, varscan2
- SACS | c.10093C>G p.L3365V | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1169280130, COSV66538657; called by muse, mutect2, varscan2
- SAG | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV68590849; called by muse, mutect2, varscan2
- SCP2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV65260967; called by muse, mutect2
- SEMA3E | c.1891A>T p.R631* | Nonsense Mutation (SNP) | VAF 53/332 reads (16%) | catalogued as COSV57087055; called by muse, mutect2, varscan2
- SLC38A10 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55844777, COSV55847529; called by muse, mutect2, varscan2
- SOX5 | c.448A>T p.K150* | Nonsense Mutation (SNP) | VAF 51/380 reads (13%) | catalogued as COSV58626961; called by muse, mutect2, varscan2
- SPANXD | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 29/552 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs145377089, COSV100982246, COSV65152327; called by muse, mutect2
- SPRED1 | c.201C>G p.D67E | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54435707; called by muse, mutect2, varscan2
- STAG2 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs776905490, COSV54351219; called by muse, mutect2, varscan2
- STT3A | c.995C>A p.S332* | Nonsense Mutation (SNP) | VAF 73/412 reads (18%) | catalogued as COSV67064588; called by muse, mutect2, varscan2
- TCF12 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 71/467 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV51005418; called by muse, mutect2, varscan2
- TCF12 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 70/452 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs745803628, COSV51005427; called by muse, varscan2
- TTC21B | c.3946C>A p.P1316T | Missense Mutation (SNP) | VAF 69/376 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54629749; called by muse, mutect2, varscan2
- TTN | c.64296G>C p.K21432N (on ENST00000591111; = p.K14008N on NM_003319.4) | Missense Mutation (SNP) | VAF 12/194 reads (6%) | PolyPhen possibly damaging (0.494); catalogued as COSV60000587; called by muse, mutect2
- UBE2Q1 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV52724770; called by muse, mutect2, varscan2
- ZNF256 | c.769C>G p.H257D | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV56597086; called by muse, mutect2
- ZNF641 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56389991; called by muse, mutect2
- ZNF765 | c.143A>T p.D48V | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV67182380; called by muse, mutect2, varscan2
- CACNG5 | c.57_58dup p.G20Vfs*22 | Frame Shift Ins (INS) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- NPEPPS | c.434del p.K145Rfs*2 | Frame Shift Del (DEL) | VAF 28/224 reads (13%) | called by mutect2, varscan2
- PDK4 | c.914del p.R305Pfs*14 | Frame Shift Del (DEL) | VAF 46/382 reads (12%) | called by mutect2, pindel, varscan2
- PSD3 | c.1138del p.S380Pfs*102 | Frame Shift Del (DEL) | VAF 35/288 reads (12%) | called by mutect2, pindel, varscan2
- TJP2 | c.1312dup p.R438Kfs*23 | Frame Shift Ins (INS) | VAF 47/306 reads (15%) | called by mutect2, pindel, varscan2
- TM4SF18 | c.516_535del p.V173Sfs*39 | Frame Shift Del (DEL) | VAF 38/332 reads (11%) | called by mutect2, pindel
- VHL | c.411del p.P138Hfs*21 | Frame Shift Del (DEL) | VAF 56/379 reads (15%) | called by mutect2, pindel, varscan2
- CACNA1S | c.2172G>A p.E724= | Silent (SNP) | VAF 53/312 reads (17%) | catalogued as COSV62938788; called by muse, mutect2, varscan2
- COL19A1 | c.2562C>T p.G854= | Silent (SNP) | VAF 92/611 reads (15%) | catalogued as COSV59570853; called by muse, mutect2, varscan2
- DMXL2 | c.5292T>C p.T1764= | Silent (SNP) | VAF 50/337 reads (15%) | catalogued as COSV51844672; called by muse, mutect2
- IL1RAPL2 | c.792C>G p.P264= | Silent (SNP) | VAF 82/640 reads (13%) | catalogued as COSV61153293; called by muse, mutect2
- ITSN1 | c.1047G>C p.T349= | Silent (SNP) | VAF 39/243 reads (16%) | catalogued as COSV66082655; called by muse, mutect2, varscan2
- JAKMIP3 | c.1782C>G p.L594= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as COSV53822343; called by muse, mutect2
- KBTBD4 | c.429A>G p.Q143= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as COSV55454280; called by muse, mutect2, varscan2
- MPP1 | c.960G>T p.P320= | Silent (SNP) | VAF 36/248 reads (15%) | catalogued as COSV65729389; called by muse, varscan2
- OR2B3 | c.853T>C p.L285= | Silent (SNP) | VAF 34/234 reads (15%) | catalogued as rs761494423, COSV65850885; called by muse, mutect2, varscan2
- OTULIN | c.954C>T p.V318= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as rs1258583728, COSV52505439; called by muse, mutect2, varscan2
- PPP1R9A | c.1239C>T p.D413= | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as COSV56889891; called by muse, mutect2, varscan2
- SLC26A4 | c.1324C>T p.L442= | Silent (SNP) | VAF 34/418 reads (8%) | catalogued as COSV55915900; called by muse, mutect2
- STRN4 | c.1464G>C p.R488= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as COSV54417914; called by muse, mutect2, varscan2
- TFDP3 | c.351G>A p.K117= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV59536557; called by muse, mutect2, varscan2
- TSEN2 | c.690C>T p.L230= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs772295412, COSV53188505; called by muse, mutect2, varscan2
- WDR75 | c.693G>A p.R231= | Silent (SNP) | VAF 70/530 reads (13%) | catalogued as COSV59105384; called by muse, varscan2
- ZKSCAN3 | c.477A>G p.Q159= | Silent (SNP) | VAF 30/271 reads (11%) | catalogued as COSV52852238; called by muse, mutect2, varscan2
- IFNL2 | c.-2G>T | 5'UTR (SNP) | VAF 18/132 reads (14%) | catalogued as COSV100122083; called by muse, mutect2, varscan2
